Somatic mutation profile of tumor specimen TCGA-HE-A5NI-01A (aliquot TCGA-HE-A5NI-01A-11D-A26P-10) from TCGA case TCGA-HE-A5NI, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-HE-A5NI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f11e2a4-f525-4459-b362-27f5c32d3855.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-A5NI-10A (Blood Derived Normal), aliquot TCGA-HE-A5NI-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aa0ec07-cfb7-44fa-89ef-08a8a5b959d1

The open-access MAF lists 126 somatic variants for this specimen: 90 protein-altering or splice-affecting, 27 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 27, Frame Shift Del 18, Frame Shift Ins 5, 3'UTR 4, Nonsense Mutation 4, 5'UTR 3, Intron 2, In Frame Del 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP17A | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV58309654; called by muse, varscan2
- AP1G1 | c.2218A>T p.S740C | Missense Mutation (SNP) | VAF 85/315 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV55489293; called by muse, mutect2, varscan2
- ASB7 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); catalogued as COSV58403772; called by muse, mutect2, varscan2
- ASIP | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs538816237, COSV66588360; called by muse, mutect2, varscan2
- C2orf69 | c.624T>A p.N208K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60666524; called by muse, mutect2, varscan2
- CAPN2 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.239); catalogued as COSV54336178; called by muse, mutect2, varscan2
- CARD6 | c.1384T>C p.Y462H | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs747907692, COSV54566242; called by muse, mutect2, varscan2
- CCDC74B | c.511A>C p.S171R | Missense Mutation (SNP) | VAF 179/381 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs778891774, COSV60102125; called by muse, mutect2, varscan2
- CEP162 | c.2408A>C p.E803A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57619958; called by muse, mutect2, varscan2
- CEP97 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59124612; called by muse, mutect2, varscan2
- CHGA | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV53663254; called by muse, mutect2, varscan2
- CYP26A1 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1272118884, COSV56418157; called by muse, mutect2, varscan2
- DCAF15 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV54329900; called by muse, mutect2, varscan2
- DENND4A | c.5297_5298insA p.S1766Rfs*7 | Frame Shift Ins (INS) | VAF 11/51 reads (22%) | catalogued as COSV101475237; called by mutect2, pindel, varscan2
- DMBT1 | c.984C>G p.D328E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57543848; called by mutect2, varscan2
- DNAJC14 | c.1861T>C p.F621L | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as rs1327959400, COSV54478401; called by muse, mutect2, varscan2
- DPY19L2 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.219); catalogued as COSV60543429; called by muse, mutect2, varscan2
- DST | c.2360G>A p.W787* (on ENST00000361203 / NM_001374722.1; = p.W461* on NM_001723.6) | Nonsense Mutation (SNP) | VAF 21/37 reads (57%) | catalogued as COSV55014601; called by muse, mutect2, varscan2
- DZIP1L | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1248516032, COSV59520993; called by muse, mutect2, varscan2
- EPS15 | c.34T>G p.L12V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV65531143; called by muse, mutect2, varscan2
- FBLN2 | c.2756A>G p.N919S | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55484542; called by muse, mutect2, varscan2
- FRMD4B | c.908A>G p.Y303C | Missense Mutation (SNP) | VAF 56/92 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV68328675, COSV68328903; called by muse, mutect2, varscan2
- GCNT3 | c.563T>C p.I188T | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV68532195; called by muse, mutect2, varscan2
- GPLD1 | c.1445A>G p.K482R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV57757036; called by muse, mutect2, varscan2
- GPR21 | c.819G>T p.L273F | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV65378952; called by muse, mutect2, varscan2
- GPRC5D | c.761T>A p.L254Q | Missense Mutation (SNP) | VAF 122/231 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57432730; called by muse, mutect2, varscan2
- HADHA | c.1098T>G p.I366M | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV66107321; called by muse, mutect2, varscan2
- ILRUN | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.443); catalogued as rs369638409; called by muse, mutect2, varscan2
- IPO4 | c.1264T>A p.S422T | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV55779523; called by muse, mutect2, varscan2
- ITGAX | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs774736704, COSV51645670; called by muse, mutect2, varscan2
- ITGB5 | c.1114A>T p.I372F | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV56149010; called by muse, mutect2, varscan2
- KNG1 | c.614A>C p.N205T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53977756, COSV99405532; called by muse, mutect2, varscan2
- KRT23 | c.396+1G>C p.X132_splice | Splice Site (SNP) | VAF 33/60 reads (55%) | catalogued as COSV52927718; called by muse, mutect2, varscan2
- LARGE1 | c.1875C>T p.F625= | Splice Region (SNP) | VAF 58/174 reads (33%) | catalogued as COSV61661922; called by muse, mutect2, varscan2
- MADCAM1 | c.1066C>A p.P356T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV53128675; called by muse, mutect2, varscan2
- MADCAM1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV53128685; called by muse, mutect2, varscan2
- MSH3 | c.1653+1G>C p.X551_splice | Splice Site (SNP) | VAF 30/91 reads (33%) | catalogued as COSV54151972; called by muse, mutect2, varscan2
- NAPA | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 69/174 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV54550143; called by muse, mutect2, varscan2
- NIN | c.4389G>C p.E1463D | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.275); catalogued as COSV55390322; called by muse, mutect2, varscan2
- NUAK2 | c.1819del p.L607* | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as COSV100904179; called by mutect2, pindel, varscan2
- NUTM2F | c.1681G>T p.G561* | Nonsense Mutation (SNP) | VAF 40/111 reads (36%) | catalogued as COSV99479794; called by muse, varscan2
- ORC2 | c.1582A>T p.S528C | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52238689; called by muse, mutect2, varscan2
- OSBPL10 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs375455808; called by muse, mutect2, varscan2
- PLIN3 | c.1230G>C p.Q410H | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV55735291; called by muse, mutect2
- PLIN3 | c.1043T>G p.I348S | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV55735300; called by muse, mutect2, varscan2
- PLXNA2 | c.4414G>A p.G1472S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421764851, COSV65440722; called by muse, mutect2, varscan2
- PPRC1 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV53385345; called by muse, mutect2, varscan2
- PRKCD | c.1084A>T p.K362* | Nonsense Mutation (SNP) | VAF 218/419 reads (52%) | catalogued as COSV57848592; called by muse, mutect2, varscan2
- PRRG3 | c.576del p.S193Pfs*5 | Frame Shift Del (DEL) | VAF 95/164 reads (58%) | catalogued as rs772440011; called by mutect2, pindel, varscan2
- RERE | c.1861A>G p.S621G | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.982); catalogued as COSV61942136; called by muse, mutect2, varscan2
- SEMA4G | c.698G>A p.G233D | Missense Mutation (SNP) | VAF 98/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52967065; called by muse, mutect2, varscan2
- SF3B1 | c.358A>C p.K120Q | Missense Mutation (SNP) | VAF 9/238 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV59214042; called by muse, mutect2
- SRCAP | c.3654G>C p.L1218F | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52672632; called by muse, mutect2, varscan2
- ST8SIA2 | c.143T>C p.L48S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | PolyPhen benign (0.003); catalogued as COSV51569515, COSV51570672; called by muse, mutect2, varscan2
- SYCP2L | c.1657A>G p.S553G | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.636); catalogued as rs745973210, COSV51653168; called by muse, mutect2, varscan2
- TASOR | c.3292G>C p.V1098L (on ENST00000355628 / NM_001365636.2; = p.V722L on NM_015224.3) | Missense Mutation (SNP) | VAF 142/263 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.053); catalogued as COSV62927804; called by muse, mutect2, varscan2
- TENT5C | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65616395, COSV65616470; called by muse, mutect2, varscan2
- TGFBR2 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 99/383 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55449756; called by muse, mutect2, varscan2
- TIGD4 | c.1504C>G p.L502V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV58549626; called by muse, mutect2, varscan2
- TMPO | c.522G>C p.Q174H | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.99); catalogued as rs1215275954, COSV54123222; called by muse, mutect2, varscan2
- TRIM47 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV54668316; called by muse, mutect2, varscan2
- TRIM71 | c.930C>A p.S310R | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.628); catalogued as COSV67470973; called by muse, mutect2, varscan2
- UACA | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 19/54 reads (35%) | catalogued as rs1292585112, COSV59855829; called by muse, mutect2, varscan2
- YPEL1 | c.102C>G p.D34E | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV59756855; called by muse, varscan2
- ZC3H6 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as COSV59667748; called by muse, mutect2
- ZNF292 | c.581T>A p.M194K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60539453; called by muse, mutect2, varscan2
- ZNF727 | c.528A>T p.E176D | Missense Mutation (SNP) | VAF 64/112 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.623); catalogued as COSV70701936; called by muse, mutect2, varscan2
- ATG4C | c.526dup p.I176Nfs*12 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- BRMS1L | c.204del p.E69Kfs*16 | Frame Shift Del (DEL) | VAF 68/204 reads (33%) | called by mutect2, pindel, varscan2
- C2CD3 | c.5843_5852del p.S1948Wfs*8 | Frame Shift Del (DEL) | VAF 41/101 reads (41%) | called by mutect2, pindel, varscan2
- CLK1 | c.945del p.L316* | Frame Shift Del (DEL) | VAF 85/176 reads (48%) | called by mutect2, pindel, varscan2
- GALNT6 | c.1432_1438del p.S478Tfs*14 | Frame Shift Del (DEL) | VAF 53/241 reads (22%) | called by mutect2, pindel, varscan2
- GATA1 | c.724del p.I242Sfs*7 | Frame Shift Del (DEL) | VAF 84/147 reads (57%) | called by mutect2, pindel, varscan2
- GDAP1 | c.533del p.N178Tfs*28 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- KATNBL1 | c.357_363del p.T120Wfs*42 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- MFAP3L | c.570dup p.R191* | Frame Shift Ins (INS) | VAF 41/154 reads (27%) | called by mutect2, pindel, varscan2
- MFN2 | c.230_231del p.D77Gfs*13 | Frame Shift Del (DEL) | VAF 107/335 reads (32%) | called by mutect2, pindel, varscan2
- PAM | c.156_157delinsA p.D53Ifs*37 | Frame Shift Del (DEL) | VAF 23/97 reads (24%) | called by pindel, varscan2*
- PDZRN4 | c.2024del p.N675Tfs*18 (on ENST00000402685 / NM_001164595.2; = p.N417Tfs*18 on NM_013377.4) | Frame Shift Del (DEL) | VAF 53/209 reads (25%) | called by mutect2, pindel, varscan2
- PRAMEF7 | c.1174G>T p.A392S | Missense Mutation (SNP) | VAF 66/374 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PTGR1 | c.811del p.V271Sfs*14 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | called by mutect2, varscan2
- PTGR1 | c.810del p.F270Lfs*15 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2*, pindel, varscan2*
- RNF168 | c.542dup p.L182Afs*4 | Frame Shift Ins (INS) | VAF 76/183 reads (42%) | called by mutect2, pindel, varscan2
- RNF34 | c.293_294del p.R98Mfs*41 | Frame Shift Del (DEL) | VAF 38/86 reads (44%) | called by mutect2, pindel, varscan2
- SACS | c.11644dup p.S3882Ffs*10 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | called by mutect2, pindel, varscan2
- SALL4 | c.2960del p.I987Tfs*3 | Frame Shift Del (DEL) | VAF 106/198 reads (54%) | called by mutect2, varscan2
- TECR | c.207_209del p.V70del | In Frame Del (DEL) | VAF 32/82 reads (39%) | called by mutect2, pindel, varscan2
- TRNT1 | c.452_460del p.R151_L153del | In Frame Del (DEL) | VAF 61/135 reads (45%) | called by mutect2, pindel, varscan2
- ZNF274 | c.1108_1112del p.T370Afs*30 (on ENST00000610905; = p.T265Afs*30 on NM_016324.3) | Frame Shift Del (DEL) | VAF 11/44 reads (25%) | called by mutect2, pindel, varscan2
- ZNF836 | c.2076del p.K692Nfs*43 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- ACACA | c.1515T>A p.I505= | Silent (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- ACER2 | c.481C>T p.L161= | Silent (SNP) | VAF 46/196 reads (23%) | catalogued as rs1370009299, COSV61820758; called by muse, mutect2, varscan2
- AKAP17A | c.888G>A p.E296= | Silent (SNP) | VAF 64/78 reads (82%) | catalogued as COSV58309639; called by muse, varscan2
- AKR7A3 | c.570T>C p.F190= | Silent (SNP) | VAF 104/271 reads (38%) | catalogued as rs1406142388, COSV64389254; called by muse, mutect2, varscan2
- ASXL2 | c.1506G>A p.E502= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as COSV55458821; called by muse, mutect2, varscan2
- CEP43 | c.633C>A p.P211= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs748864790, COSV62760669, COSV62760865; called by muse, mutect2, varscan2
- FN1 | c.2874G>A p.R958= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV60552865; called by muse, mutect2, varscan2
- HTR5A | c.123G>T p.V41= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV55283210; called by muse, mutect2, varscan2
- IGKV3D-11 | c.282C>A p.T94= | Silent (SNP) | VAF 48/236 reads (20%) | called by muse, mutect2, varscan2
- KIF5B | c.1539T>C p.T513= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV56652905; called by muse, mutect2, varscan2
- MAP4K4 | c.2934C>G p.V978= (on ENST00000347699 / NM_001242559.2; = p.V896= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 116/392 reads (30%) | catalogued as rs575144210, COSV56331161; called by muse, mutect2, varscan2
- METTL27 | c.663T>G p.S221= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs1216054956, COSV52895851; called by muse, mutect2, varscan2
- MZF1 | c.117C>T p.G39= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV53041560; called by muse, mutect2, varscan2
- NOTCH4 | c.3990G>A p.R1330= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV66680662; called by muse, mutect2, varscan2
- OSBPL1A | c.441A>G p.A147= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV100110900; called by muse, mutect2, varscan2
- PCSK6 | c.2280T>C p.A760= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs748198053, COSV61853034; called by muse, mutect2, varscan2
- PLCB1 | c.267T>G p.L89= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV62050897; called by muse, mutect2, varscan2
- PNRC1 | c.870T>C p.P290= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV60139675; called by muse, mutect2, varscan2
- PSMD12 | c.87C>G p.P29= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV62065710; called by muse, mutect2, varscan2
- SP7 | c.867G>A p.R289= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV58190898; called by muse, mutect2, varscan2
- SPEN | c.7728T>G p.V2576= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV65361825; called by muse, mutect2, varscan2
- SPTAN1 | c.5952G>A p.K1984= | Silent (SNP) | VAF 61/144 reads (42%) | catalogued as COSV63987128; called by muse, mutect2, varscan2
- TET3 | c.3195G>T p.G1065= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV69642606; called by muse, mutect2, varscan2
- ZC3H11A | c.2058C>T p.L686= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as COSV59746440; called by muse, mutect2, varscan2
- ZMYM1 | c.444G>C p.V148= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV63251898; called by muse, mutect2, varscan2
- ZNF274 | c.1470G>C p.R490= (on ENST00000610905; = p.R385= on NM_016324.3) | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV58764429; called by muse, mutect2, varscan2
- ZNF319 | c.396C>T p.F132= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs1483005450, COSV54622194; called by muse, mutect2, varscan2
- CKAP5 | c.-1A>G | 5'UTR (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100370255; called by muse, mutect2, varscan2
- COASY | c.*12T>G | 3'UTR (SNP) | VAF 65/134 reads (49%) | catalogued as COSV99888063; called by muse, mutect2, varscan2
- DCX | c.-22-363G>A | Intron (SNP) | VAF 68/88 reads (77%) | catalogued as rs774466898, COSV57567885; called by muse, mutect2, varscan2
- FRMPD2 | c.-8A>G | 5'UTR (SNP) | VAF 41/129 reads (32%) | catalogued as rs1253513547, COSV100951022; called by muse, mutect2, varscan2
- OR51E1 | c.*1576A>G | 3'UTR (SNP) | VAF 31/85 reads (36%) | catalogued as COSV67811018; called by muse, mutect2, varscan2
- PLN | c.*1143C>T | 3'UTR (SNP) | VAF 46/109 reads (42%) | catalogued as rs775287766, COSV100682486; called by muse, mutect2, varscan2
- RABEPK | c.-159T>A | 5'UTR (SNP) | VAF 55/143 reads (38%) | catalogued as COSV99413205; called by muse, mutect2, varscan2
- SP100 | c.2052+35C>A | Intron (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99891924; called by muse, mutect2, varscan2
- TENT5C | c.*2357G>T | 3'UTR (SNP) | VAF 36/106 reads (34%) | catalogued as COSV101032677; called by muse, mutect2, varscan2
